Somatic mutation profile of tumor specimen C3L-10135-01 (aliquot CPT0516880006) from CPTAC case C3L-10135, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 64.6 years (23,599 days).
Specimen C3L-10135-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcd95c89-d951-4aa5-b1db-d672f43312ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-10135-31 (Blood Derived Normal), aliquot CPT0517030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6a2aab0-9e35-4ab4-bcaf-0359d41536c9

The open-access MAF lists 459 somatic variants for this specimen: 332 protein-altering or splice-affecting, 114 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 310, Silent 114, Nonsense Mutation 12, Frame Shift Del 5, 3'Flank 4, RNA 4, Splice Region 4, 3'UTR 2, Intron 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 30/308 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 42/202 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 28/215 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN1 | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs745580045; called by muse, varscan2
- ADGRG1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs139207635; called by muse, mutect2, varscan2
- ALDH1A2 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs572439325, COSV51087224; called by muse, mutect2, varscan2
- ANK2 | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52178943; called by muse, mutect2, varscan2
- ANO1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs370908183; called by muse, mutect2, varscan2
- APCS | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 44/439 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV54817487, COSV54819099, COSV54819221; called by muse, mutect2, varscan2
- APLF | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 44/362 reads (12%) | catalogued as COSV58145049; called by muse, mutect2, varscan2
- ARPP21 | c.1087A>T p.S363C | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99492330; called by muse, mutect2, varscan2
- ATP13A2 | c.2995G>A p.V999M | Missense Mutation (SNP) | VAF 94/592 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as rs764162255, COSV58698137; called by muse, mutect2
- ATP1A2 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 35/474 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1463299098, COSV100767592; called by muse, mutect2
- AWAT1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs766687052, COSV65738218; called by muse, mutect2, varscan2
- BACH2 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs760300804, COSV57595293; called by muse, mutect2, varscan2
- BRINP2 | c.1733A>G p.K578R | Missense Mutation (SNP) | VAF 67/518 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV64178533; called by muse, mutect2, varscan2
- C22orf23 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760262820; called by muse, mutect2, varscan2
- CCDC141 | c.741A>C p.Q247H | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV101330557, COSV101330800; called by muse, mutect2, varscan2
- CCDC178 | c.1885T>A p.L629I | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs182556774, COSV55758501; called by muse, mutect2, varscan2
- CD1E | c.518A>C p.N173T | Missense Mutation (SNP) | VAF 67/648 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV63772721; called by muse, mutect2, varscan2
- CDK15 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as rs748922435; called by muse, mutect2, varscan2
- CLDND1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs761957957, COSV57858154, COSV57858167; called by muse, mutect2, varscan2
- CPQ | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs1363566291, COSV99610498; called by muse, mutect2, varscan2
- CPSF4L | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 47/260 reads (18%) | catalogued as rs1214949777; called by muse, mutect2, varscan2
- CRISPLD1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149414263; called by muse, mutect2, varscan2
- CYLC1 | c.248A>T p.K83I | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV61409586; called by muse, mutect2, varscan2
- CYP2A6 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs139639589; called by muse, mutect2, varscan2
- CYP7B1 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59598240; called by muse, mutect2, varscan2
- CYRIA | c.855A>C p.K285N | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62864409, COSV62865839, COSV62867483; called by muse, mutect2, varscan2
- DDX18 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs761363256; called by muse, mutect2, varscan2
- DDX53 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751629687, COSV60069066; called by muse, mutect2, varscan2
- DLGAP2 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 86/693 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs767334645; called by muse, mutect2, varscan2
- DNAH5 | c.6457T>C p.F2153L | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54261757; called by muse, mutect2, varscan2
- DOCK2 | c.4559A>G p.E1520G | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.364); catalogued as COSV56958652; called by muse, mutect2, varscan2
- EDIL3 | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56879439; called by muse, mutect2, varscan2
- EHBP1L1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1043571282; called by muse, mutect2, varscan2
- ELFN2 | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 138/550 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs755029989, COSV68746259; called by muse, mutect2, varscan2
- EPB41L3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 51/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59450932; called by muse, mutect2, varscan2
- EPHA4 | c.2272T>G p.L758V | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV56026391; called by muse, mutect2, varscan2
- EVC | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99381130; called by muse, mutect2, varscan2
- EVC | c.1148A>C p.E383A | Missense Mutation (SNP) | VAF 61/383 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV53830017; called by muse, mutect2, varscan2
- EXD3 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs754981932, COSV59803012; called by muse, varscan2
- F10 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs373791924; called by muse, mutect2, varscan2
- FAT1 | c.13412C>T p.A4471V | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs375425015; called by muse, mutect2, varscan2
- FAT3 | c.1954A>G p.R652G | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99971198; called by muse, mutect2, varscan2
- FLNB | c.3020T>A p.I1007N | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.875); catalogued as rs533382927; called by muse, mutect2, varscan2
- FSTL5 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60183600, COSV60210915; called by muse, mutect2, varscan2
- FZD10 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV57475636; called by muse, mutect2, varscan2
- GABRA1 | c.1042A>C p.S348R | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV50099571, COSV99195668; called by muse, mutect2, varscan2
- GGH | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1160209185, COSV52651040; called by muse, mutect2
- GIT1 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs746766343; called by muse, mutect2, varscan2
- GLB1L3 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779268002, COSV68392808; called by muse, mutect2, varscan2
- GLP1R | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs761383378; called by muse, mutect2, varscan2
- GPR45 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 50/411 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs527336507; called by muse, mutect2, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HECW1 | c.3243A>T p.E1081D | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV67840036; called by muse, varscan2
- HIRA | c.2944C>T p.R982W | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1556004628; called by muse, mutect2, varscan2
- HOXD9 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 130/520 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV50890486; called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.163T>C p.W55R | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1185690623; called by muse, mutect2
- IL1RAPL2 | c.236A>C p.N79T | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.026); catalogued as COSV100780723; called by muse, mutect2, varscan2
- IPP | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | catalogued as rs757516477, COSV63432781; called by muse, mutect2, varscan2
- IQCN | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 66/484 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs144107214; called by muse, mutect2, varscan2
- JAG1 | c.3569C>T p.P1190L | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1334807463; called by muse, mutect2, varscan2
- KCNA3 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 55/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63902574; called by muse, mutect2, varscan2
- KCNC3 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 65/361 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs770686560; called by muse, varscan2
- KCNJ5 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV57966588; called by muse, mutect2, varscan2
- KCNMB2 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV100844033; called by muse, mutect2, varscan2
- KCNQ5 | c.1258A>C p.S420R | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV59662086, COSV59665050; called by muse, mutect2, varscan2
- KHDRBS2 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV55447094, COSV55484583; called by muse, mutect2, varscan2
- KIF1A | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434341247, COSV57485378; called by muse, mutect2, varscan2
- KIRREL3 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as rs559592356, COSV101375162; called by muse, varscan2
- LMNA | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749784223, COSV61542876; called by muse, mutect2
- LMTK3 | c.3846C>G p.D1282E | Missense Mutation (SNP) | VAF 71/548 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs1207811572; called by muse, mutect2, varscan2
- MAGEB5 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1170322916, COSV66868659; called by muse, mutect2, varscan2
- MAGEC3 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV53575632, COSV53580495; called by muse, mutect2, varscan2
- MGAT4C | c.1175T>G p.I392S | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV59833204; called by muse, mutect2, varscan2
- MLNR | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 71/481 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1317231669; called by muse, mutect2, varscan2
- MME | c.1943A>C p.N648T | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852626; called by muse, mutect2
- MMP10 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs766298525; called by muse, mutect2, varscan2
- MORF4L2 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as rs780524142; called by muse, mutect2, varscan2
- MPDZ | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as rs367828845; called by muse, mutect2, varscan2
- MTNR1B | c.943T>G p.F315V | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57065291; called by muse, mutect2, varscan2
- MYCN | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324334894, COSV99807954; called by muse, mutect2, varscan2
- NAB2 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.184); catalogued as COSV55665692; called by muse, mutect2, varscan2
- NAV3 | c.3884C>T p.T1295M | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs189835133, COSV99887506; called by muse, mutect2, varscan2
- NBPF15 | c.1302A>T p.E434D | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV64993322; called by muse, mutect2
- NEFH | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs1384934559; called by muse, mutect2, varscan2
- NEUROD2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.361); catalogued as rs750514554; called by muse, mutect2, varscan2
- NEUROG2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs780585632, COSV57637170; called by muse, mutect2, varscan2
- NLGN3 | c.1576G>A p.E526K (on ENST00000358741 / NM_181303.2; = p.E506K on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100705020; called by muse, mutect2
- NLRP5 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs367708838; called by muse, mutect2, varscan2
- NME8 | c.1675A>C p.S559R | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1330765391, COSV52246197, COSV52252862; called by muse, mutect2, varscan2
- NOTUM | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as rs776143547, COSV101293744; called by muse, mutect2, varscan2
- NSUN4 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 53/373 reads (14%) | catalogued as rs189515964, COSV61062562; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 41/378 reads (11%) | catalogued as rs780417788; called by mutect2, varscan2
- NYAP2 | c.1294A>T p.S432C | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV56017933; called by muse, mutect2, varscan2
- OR10A6 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59164986; called by muse, mutect2, varscan2
- OR10J3 | c.353T>G p.V118G | Missense Mutation (SNP) | VAF 108/444 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV59953731; called by muse, mutect2, varscan2
- OR14J1 | c.884T>C p.M295T | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1421639130; called by muse, mutect2, varscan2
- OR2D3 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1455135482; called by muse, mutect2
- OR4C6 | c.182T>G p.L61R | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58603234; called by muse, mutect2, varscan2
- OR51I1 | c.190T>A p.F64I | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV66507562, COSV66508444; called by muse, mutect2, varscan2
- OR8J3 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV56880069, COSV56881430; called by muse, mutect2, varscan2
- OR9K2 | c.209T>G p.M70R (on ENST00000305377; = p.M48R on NM_001005243.1) | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59532635; called by muse, mutect2, varscan2
- P2RY1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.775); catalogued as COSV59309268; called by muse, mutect2, varscan2
- PCDHA6 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV65355249; called by muse, mutect2, varscan2
- PCDHB16 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 58/462 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1371346092, COSV53357605; called by muse, mutect2
- PCDHGA3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.013); catalogued as rs759248221; called by muse, mutect2
- PCDHGA8 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as rs750632906, COSV53931165; called by muse, mutect2, varscan2
- PCLO | c.10954A>C p.S3652R | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100439825, COSV61659264; called by muse, mutect2
- PCLO | c.7070C>A p.S2357* | Nonsense Mutation (SNP) | VAF 68/391 reads (17%) | catalogued as COSV61617187, COSV61618623; called by muse, mutect2, varscan2
- PCLO | c.6417A>C p.E2139D | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV61612531, COSV61635435; called by muse, mutect2
- PDGFD | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755849936, COSV100160702, COSV56394207; called by muse, mutect2, varscan2
- PGBD5 | c.896C>T p.A299V (on ENST00000525115; = p.A368V on NM_001258311.2) | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs889200747; called by muse, varscan2
- PHACTR3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs747934926, COSV63025654; called by muse, mutect2, varscan2
- PHF24 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1234401851, COSV54275551; called by muse, mutect2, varscan2
- PLPPR4 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1335555385, COSV64565728; called by muse, mutect2, varscan2
- POLR1A | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs759002063; called by muse, mutect2, varscan2
- POU6F2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 84/559 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs775328548; called by muse, mutect2, varscan2
- PRICKLE1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774440655, COSV61543138, COSV61545370; called by muse, mutect2, varscan2
- PROB1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 67/407 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV56172083; called by muse, mutect2, varscan2
- PRRX1 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53410909, COSV99509643; called by muse, mutect2, varscan2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 59/478 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, mutect2, varscan2
- RCBTB2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs756972614; called by muse, mutect2, varscan2
- RECQL4 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 120/524 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368601097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX4 | c.467C>T p.T156M (on ENST00000392842 / NM_213594.3; = p.T62M on NM_032491.6) | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs970724399, COSV57580415; called by muse, varscan2
- RGS19 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs750611686, COSV58658848; called by muse, mutect2, varscan2
- ROS1 | c.6115C>T p.R2039C | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752085591, COSV63854894; called by muse, mutect2, varscan2
- RYR1 | c.8137G>A p.D2713N | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765571437, COSV62110442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV66077948; called by muse, mutect2, varscan2
- SCN8A | c.5578G>A p.G1860R | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1457529194; called by muse, mutect2, varscan2
- SCN9A | c.5123T>G p.L1708R (on ENST00000303354; = p.L1697R on NM_002977.3) | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57599454, COSV57620411; called by muse, mutect2, varscan2
- SEL1L3 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs568228150; called by muse, mutect2, varscan2
- SINHCAF | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV61797126; called by muse, mutect2, varscan2
- SLCO5A1 | c.1370A>C p.K457T | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99036091; called by muse, mutect2, varscan2
- SPEG | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 118/547 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as rs1170695473; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2624G>A p.S875N | Missense Mutation (SNP) | VAF 66/389 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59139405; called by muse, mutect2
- SYCP2 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100698511; called by muse, mutect2, varscan2
- TAGAP | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs201023356; called by muse, mutect2, varscan2
- TCHH | c.5660G>A p.R1887H | Missense Mutation (SNP) | VAF 151/458 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as rs201952511, COSV64278390; called by muse, varscan2
- TLR4 | c.304A>C p.S102R (on ENST00000355622 / NM_138554.5; = p.S62R on NM_003266.4) | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV62923942; called by muse, mutect2, varscan2
- TNR | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 64/461 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs780299242, COSV54888167; called by muse, mutect2, varscan2
- TRIM49B | c.450A>C p.K150N | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs905007989; called by muse, mutect2, varscan2
- TRO | c.626A>C p.K209T | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV51500453; called by muse, mutect2, varscan2
- TSKU | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 63/377 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as rs780008118, COSV60752972; called by muse, mutect2, varscan2
- TTC21A | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs199645072; called by muse, mutect2
- TTN | c.15005A>C p.K5002T (on ENST00000591111; = p.K4075T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/410 reads (12%) | PolyPhen probably damaging (0.964); catalogued as rs779733584, COSV60238842; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBB4A | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 67/449 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as rs1276141920; called by muse, mutect2, varscan2
- TUT1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 46/336 reads (14%) | catalogued as rs756305648; called by muse, mutect2, varscan2
- UNC13C | c.4004A>T p.K1335M | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); catalogued as COSV52845640, COSV99512011; called by muse, mutect2, varscan2
- UNC79 | c.6005C>T p.T2002M (on ENST00000393151 / NM_001346218.2; = p.T1825M on NM_020818.5) | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs767976870, COSV56376523; called by muse, varscan2
- UTRN | c.710T>G p.L237R | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV62338339; called by muse, varscan2
- WASF3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs755864030, COSV58972181; called by muse, mutect2, varscan2
- WNT10B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536694627, COSV56404859, COSV56405318; called by muse, mutect2, varscan2
- XDH | c.636del p.P214Qfs*4 | Frame Shift Del (DEL) | VAF 35/336 reads (10%) | catalogued as rs746274457; called by mutect2, pindel, varscan2
- XKR7 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1348741898; called by muse, mutect2
- ZFYVE28 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369109308; called by muse, mutect2, varscan2
- ZIC1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51550649; called by muse, mutect2, varscan2
- ZNF347 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 57/399 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61967657; called by muse, mutect2, varscan2
- ZNF507 | c.1663A>C p.T555P | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs758264670; called by muse, mutect2, varscan2
- ZNF521 | c.1796A>C p.K599T | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV64123908, COSV64126866; called by muse, mutect2, varscan2
- ZNF569 | c.449T>G p.F150C | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as COSV57597957; called by muse, mutect2, varscan2
- ZNF662 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs781485218; called by muse, mutect2, varscan2
- ZNF71 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs747899140, COSV60150914; called by muse, mutect2, varscan2
- ZNF727 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as COSV101407052; called by muse, mutect2
- ABCA3 | c.2914G>T p.V972F | Missense Mutation (SNP) | VAF 64/430 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ABCB1 | c.2498T>C p.L833P | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC008687.4 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ACSS3 | c.615A>T p.K205N | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACSS3 | c.1353T>C p.T451= | Splice Region (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- ACTG2 | c.380C>G p.T127S | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRB3 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ADGRG7 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- AGTR1 | c.640A>C p.S214R | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AJM1 | c.2217_2223del p.I739Mfs*110 | Frame Shift Del (DEL) | VAF 110/460 reads (24%) | called by mutect2, pindel, varscan2
- AL590132.1 | c.1307T>A p.F436Y | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated, low confidence (0.67); called by muse, mutect2, varscan2
- ALDH1L1 | c.1328A>C p.N443T | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ANKFN1 | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ANKRD28 | c.2337A>C p.E779D | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- AP002512.3 | c.1009A>G p.R337G | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ARFGAP1 | c.952C>G p.H318D | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP20 | c.3173G>T p.R1058I | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by mutect2, varscan2
- ASAH1 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ASAH1 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ASTN2 | c.2208T>G p.G736= (on ENST00000313400 / NM_001365069.1; = p.G685= on NM_014010.5) | Splice Region (SNP) | VAF 24/180 reads (13%) | called by muse, mutect2, varscan2
- ATM | c.1724C>G p.S575* | Nonsense Mutation (SNP) | VAF 30/228 reads (13%) | called by muse, mutect2, varscan2
- ATRNL1 | c.2370A>C p.K790N | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- BBS4 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA2D1 | c.3037T>G p.L1013V (on ENST00000356253 / NM_001366867.1; = p.L1001V on NM_000722.4) | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL7 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CD101 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CFH | c.2594T>G p.V865G | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CFHR5 | c.1150A>C p.K384Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CHD8 | c.3581G>A p.R1194H (on ENST00000646647 / NM_001170629.2; = p.R915H on NM_020920.4) | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST15 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by mutect2, varscan2
- CLEC12A | c.57A>C p.E19D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- COL22A1 | c.4655T>G p.V1552G | Missense Mutation (SNP) | VAF 100/386 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CPA3 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSMD1 | c.6554T>G p.V2185G (on ENST00000520002; = p.V2184G on NM_033225.6) | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CSMD1 | c.3587A>C p.N1196T (on ENST00000520002; = p.N1195T on NM_033225.6) | Missense Mutation (SNP) | VAF 27/375 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSMD3 | c.5341A>C p.N1781H (on ENST00000297405 / NM_001363185.1; = p.N1677H on NM_052900.3) | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CSNKA2IP | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- DCC | c.1151A>C p.N384T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- DCLK2 | c.166T>G p.F56V | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DLX6 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DNAH5 | c.11642A>C p.K3881T | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOCK10 | c.2665T>G p.L889V | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DSEL | c.2817C>G p.D939E | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ENOX1 | c.795A>C p.E265D | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FANCC | c.41T>G p.F14C | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAT2 | c.9494C>T p.T3165I | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FAT4 | c.14655T>G p.N4885K | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FCGR2B | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 77/499 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FERMT3 | c.1541A>C p.K514T (on ENST00000279227 / NM_178443.3; = p.K510T on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FOXP2 | c.662T>G p.L221R | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.979); called by muse, varscan2
- FSIP2 | c.17460T>G p.N5820K | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- FZD2 | c.1501A>C p.S501R | Missense Mutation (SNP) | VAF 65/430 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAK | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GNAI1 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- GNPDA2 | c.531T>A p.D177E | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GP2 | c.93A>G p.R31= | Splice Region (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- GPR141 | c.58T>G p.L20V | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA4 | c.1827A>T p.Q609H | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIK1 | c.1883G>A p.W628* | Nonsense Mutation (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.303G>A p.S101= | Splice Region (SNP) | VAF 30/267 reads (11%) | called by muse, mutect2, varscan2
- HDAC4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HECTD1 | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2
- HTR2A | c.1193A>C p.Q398P | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- IFT172 | c.3126A>C p.E1042D | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, varscan2
- IGFBP1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 78/621 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- IGFBP3 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 60/498 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- IGFBP7 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 64/457 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHA2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- IGHM | c.1097T>A p.M366K | Missense Mutation (SNP) | VAF 68/418 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- IGLV2-8 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 105/483 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IRS4 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JARID2 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LAMA5 | c.9599C>A p.A3200D | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- LCE2C | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 76/614 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- LMTK3 | c.3428C>T p.P1143L | Missense Mutation (SNP) | VAF 79/559 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRFN4 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 77/507 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- LRP1B | c.7202T>G p.V2401G | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LRP1B | c.2195T>C p.V732A | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LRRN1 | c.760G>T p.V254F | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- LVRN | c.2148A>C p.E716D | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MAPK4 | c.1511C>G p.P504R | Missense Mutation (SNP) | VAF 67/418 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MC3R | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 47/457 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MKLN1 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.175); called by muse, mutect2
- MUC16 | c.3225A>C p.K1075N | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MUC16 | c.2555C>A p.S852* | Nonsense Mutation (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- MYO7A | c.4127A>C p.K1376T | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- NAA16 | c.835del p.I279Ffs*20 | Frame Shift Del (DEL) | VAF 28/207 reads (14%) | called by mutect2, pindel, varscan2
- NCOA6 | c.4213G>C p.V1405L | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NKG7 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRIP1 | c.3074C>T p.P1025L | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1J4 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR2J3 | c.257del p.V86Afs*16 | Frame Shift Del (DEL) | VAF 65/498 reads (13%) | called by mutect2, pindel, varscan2
- OR4X1 | c.5T>G p.V2G | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6K2 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 147/443 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- OR8H2 | c.247T>A p.L83I | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PARP10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHA1 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 71/483 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PCDHB4 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, varscan2
- PCDHB4 | c.53T>G p.L18W | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by muse, varscan2
- PCLO | c.12586A>C p.I4196L | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2
- PCLO | c.8840T>G p.L2947* | Nonsense Mutation (SNP) | VAF 42/306 reads (14%) | called by muse, varscan2
- PCSK5 | c.5095G>T p.D1699Y | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PITX2 | c.662G>C p.S221T (on ENST00000354925 / NM_001204397.1; = p.S228T on NM_000325.6) | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PKD1 | c.11735T>A p.V3912E (on ENST00000262304 / NM_001009944.3; = p.V3911E on NM_000296.4) | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PKP1 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PLD4 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PLPPR2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 71/508 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- POGZ | c.3885T>A p.D1295E | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POM121C | c.684T>G p.N228K | Missense Mutation (SNP) | VAF 71/489 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- POU4F3 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PPP4R3C | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRIMPOL | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 31/215 reads (14%) | called by muse, mutect2, varscan2
- PRPF4B | c.1189T>G p.L397V | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTH1R | c.1510A>C p.S504R | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, varscan2
- PTK7 | c.3011A>T p.E1004V | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTPN13 | c.3062T>G p.L1021R | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PWWP3B | c.1899T>G p.I633M | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- RAPGEF3 | c.137G>A p.R46K (on ENST00000389212; = p.R4K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/369 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS2 | c.1774A>G p.S592G (on ENST00000666250 / NM_001348490.2; = p.S400G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIPOR1 | c.2906C>T p.P969L (on ENST00000379312 / NM_001193522.2; = p.P965L on NM_024519.4) | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RORA | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SBNO2 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- SCN2A | c.4509A>C p.K1503N | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- SCRT2 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA4D | c.2558A>C p.K853T | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SEMA7A | c.820A>G p.S274G | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- SFRP1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 61/450 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SFTPA2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2
- SLC22A5 | c.1307A>C p.K436T | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9A1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 56/380 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLITRK2 | c.2326T>C p.F776L | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- SPANXN2 | c.154A>T p.I52L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SPOCK3 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPRR2G | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 29/283 reads (10%) | PolyPhen benign (0.26); called by muse, mutect2
- SPTA1 | c.1502A>C p.N501T | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- STK36 | c.1187del p.P396Qfs*11 | Frame Shift Del (DEL) | VAF 69/267 reads (26%) | called by mutect2, pindel, varscan2
- STXBP4 | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SULT1C3 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SYNE1 | c.616A>T p.S206C (on ENST00000367255 / NM_182961.4; = p.S213C on NM_033071.3) | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TFR2 | c.1885C>T p.L629F | Missense Mutation (SNP) | VAF 67/437 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- TLR4 | c.704A>C p.N235T (on ENST00000355622 / NM_138554.5; = p.N195T on NM_003266.4) | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLR4 | c.2231G>C p.S744T (on ENST00000355622 / NM_138554.5; = p.S704T on NM_003266.4) | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132D | c.1778A>G p.H593R | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, varscan2
- TMEM132D | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, varscan2
- TRIM48 | c.467T>G p.L156R | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRO | c.1763A>C p.K588T | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTC3 | c.4997T>G p.F1666C | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC9 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP43 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDFY4 | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- WDFY4 | c.6656A>G p.K2219R | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR93 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 96/309 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WNT5A | c.176A>G p.E59G | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- XIRP2 | c.542A>G p.E181G (on ENST00000628543; = p.E356G on NM_152381.6) | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBED9 | c.3344T>G p.L1115R | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZBED9 | c.1987A>C p.S663R | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZC3H11B | c.2138A>T p.K713I | Missense Mutation (SNP) | VAF 30/668 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2
- ZFP28 | c.1850T>G p.F617C | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZFP37 | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ZFP92 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF281 | c.359T>G p.F120C | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZNF354C | c.450T>A p.H150Q | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF567 | c.1255A>G p.K419E (on ENST00000536254 / NM_001322913.1; = p.K388E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF707 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 64/641 reads (10%) | called by muse, varscan2
- ZNF717 | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- ZNF729 | c.2801A>C p.K934T | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ABCB1 | c.987A>G p.G329= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV55959269; called by muse, mutect2, varscan2
- ABI3 | c.258G>A p.V86= | Silent (SNP) | VAF 85/330 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.1332G>A p.L444= | Silent (SNP) | VAF 56/290 reads (19%) | called by muse, mutect2, varscan2
- ADCY8 | c.1752T>G p.T584= | Silent (SNP) | VAF 52/464 reads (11%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2, varscan2
- ADD2 | c.21C>T p.P7= | Silent (SNP) | VAF 59/386 reads (15%) | catalogued as rs782347196; called by muse, mutect2, varscan2
- ADPRHL1 | c.2730G>A p.A910= | Silent (SNP) | VAF 46/309 reads (15%) | catalogued as rs953279035; called by muse, mutect2, varscan2
- AICDA | c.480A>G p.K160= | Silent (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- ANKRD20A2P | c.141G>A p.A47= | Silent (SNP) | VAF 67/1574 reads (4%) | catalogued as rs774142152; called by muse, mutect2
- BATF2 | c.591C>A p.P197= | Silent (SNP) | VAF 80/483 reads (17%) | called by muse, mutect2, varscan2
- BOC | c.2574C>T p.V858= | Silent (SNP) | VAF 53/391 reads (14%) | catalogued as rs1040442794; called by muse, mutect2, varscan2
- C10orf90 | c.60T>C p.I20= | Silent (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- C2CD4C | c.543C>T p.A181= | Silent (SNP) | VAF 59/435 reads (14%) | catalogued as rs763016255; called by muse, mutect2, varscan2
- C3orf20 | c.1743G>T p.R581= | Silent (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
- CACNA1A | c.2307G>A p.K769= | Silent (SNP) | VAF 45/280 reads (16%) | catalogued as rs1287136668, COSV64197587; called by muse, mutect2, varscan2
- CACTIN | c.1428C>T p.S476= | Silent (SNP) | VAF 48/364 reads (13%) | catalogued as COSV50266592; called by muse, mutect2, varscan2
- CFAP47 | c.8058C>G p.V2686= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- CFHR5 | c.667A>C p.R223= | Silent (SNP) | VAF 43/305 reads (14%) | catalogued as COSV56822359; called by muse, mutect2, varscan2
- CLTCL1 | c.2970C>T p.V990= | Silent (SNP) | VAF 38/323 reads (12%) | catalogued as rs782552927; called by muse, mutect2, varscan2
- CLUH | c.1290C>T p.F430= (on ENST00000435359; = p.F468= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/296 reads (27%) | catalogued as rs779182856; called by muse, mutect2, varscan2
- CNTNAP5 | c.3741G>T p.V1247= | Silent (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- CREB5 | c.834G>A p.P278= (on ENST00000357727 / NM_182898.4; = p.P271= on NM_004904.3) | Silent (SNP) | VAF 83/501 reads (17%) | catalogued as rs139638068, COSV100745528; called by mutect2, varscan2
- CUBN | c.1791T>G p.P597= | Silent (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2, varscan2
- DAB2 | c.981G>A p.S327= | Silent (SNP) | VAF 47/377 reads (12%) | catalogued as rs753430742, COSV57914602; called by muse, mutect2, varscan2
- DLL3 | c.789G>A p.P263= | Silent (SNP) | VAF 74/489 reads (15%) | catalogued as rs773579241, COSV52693845; called by muse, mutect2, varscan2
- DNAH11 | c.5640T>G p.T1880= | Silent (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2
- DOCK10 | c.4320T>G p.T1440= | Silent (SNP) | VAF 36/320 reads (11%) | catalogued as rs1377566404, COSV99292452; called by muse, mutect2, varscan2
- EPHA3 | c.1785T>G p.T595= | Silent (SNP) | VAF 33/215 reads (15%) | catalogued as COSV100349806; called by muse, mutect2, varscan2
- F8 | c.1200T>A p.T400= | Silent (SNP) | VAF 64/212 reads (30%) | called by muse, mutect2, varscan2
- FAM205A | c.15T>G p.T5= | Silent (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- FAM20C | c.234C>T p.G78= | Silent (SNP) | VAF 48/536 reads (9%) | catalogued as rs1263950129; called by muse, mutect2
- FBXO24 | c.606C>T p.Y202= (on ENST00000241071 / NM_033506.3; = p.Y240= on NM_012172.5) | Silent (SNP) | VAF 41/261 reads (16%) | catalogued as rs374971411; called by muse, mutect2, varscan2
- FCRL4 | c.588A>G p.K196= | Silent (SNP) | VAF 17/242 reads (7%) | catalogued as COSV99619061; called by muse, mutect2
- FXR1 | c.444A>G p.K148= | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as rs775172243; called by muse, mutect2, varscan2
- GAK | c.1740G>A p.V580= | Silent (SNP) | VAF 42/319 reads (13%) | called by muse, mutect2, varscan2
- GDF2 | c.183C>T p.N61= | Silent (SNP) | VAF 62/358 reads (17%) | catalogued as rs1255787900; called by muse, mutect2, varscan2
- GLI3 | c.477T>G p.T159= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as COSV101229980; called by muse, mutect2, varscan2
- GNAI2 | c.555C>T p.I185= | Silent (SNP) | VAF 28/256 reads (11%) | catalogued as rs781955898; called by muse, mutect2, varscan2
- GRM7 | c.318G>A p.L106= | Silent (SNP) | VAF 54/445 reads (12%) | called by muse, mutect2, varscan2
- HERC2 | c.1641G>A p.K547= | Silent (SNP) | VAF 63/386 reads (16%) | called by muse, mutect2, varscan2
- HS6ST2 | c.66C>T p.P22= | Silent (SNP) | VAF 67/236 reads (28%) | called by muse, mutect2, varscan2
- ID4 | c.165G>A p.A55= | Silent (SNP) | VAF 34/334 reads (10%) | catalogued as rs760192956; called by muse, varscan2
- IGHV4-39 | c.177T>C p.S59= | Silent (SNP) | VAF 39/258 reads (15%) | catalogued as rs770317004; called by muse, mutect2, varscan2
- IL17RE | c.96C>T p.P32= | Silent (SNP) | VAF 54/367 reads (15%) | catalogued as rs1203004673; called by muse, mutect2, varscan2
- IQCE | c.684G>A p.E228= | Silent (SNP) | VAF 51/398 reads (13%) | called by muse, mutect2, varscan2
- KIAA0825 | c.1524T>G p.S508= | Silent (SNP) | VAF 50/259 reads (19%) | called by muse, mutect2, varscan2
- KIRREL2 | c.843C>T p.D281= | Silent (SNP) | VAF 46/379 reads (12%) | catalogued as rs1487303105, COSV52875596; called by muse, mutect2, varscan2
- KLHL29 | c.2382C>T p.Y794= | Silent (SNP) | VAF 62/332 reads (19%) | catalogued as rs368696669, COSV71992647; called by muse, mutect2
- KRT73 | c.1245C>T p.R415= | Silent (SNP) | VAF 87/265 reads (33%) | catalogued as rs759751275; called by muse, mutect2, varscan2
- KRTAP22-1 | c.114T>C p.C38= | Silent (SNP) | VAF 34/255 reads (13%) | catalogued as rs1331743531; called by muse, varscan2
- L3MBTL4 | c.1231T>C p.L411= | Silent (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- LAMA5 | c.11055G>A p.G3685= | Silent (SNP) | VAF 59/431 reads (14%) | called by muse, mutect2, varscan2
- LAMA5 | c.633C>T p.D211= | Silent (SNP) | VAF 51/391 reads (13%) | catalogued as rs765518344, COSV53362071; called by muse, mutect2, varscan2
- MDFIC | c.306T>A p.G102= | Silent (SNP) | VAF 53/344 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.14964T>A p.T4988= | Silent (SNP) | VAF 42/308 reads (14%) | catalogued as COSV101202432, COSV67465430, COSV67491364; called by muse, mutect2, varscan2
- MUC19 | c.921T>G p.T307= | Silent (SNP) | VAF 30/248 reads (12%) | catalogued as COSV66447245; called by muse, mutect2, varscan2
- MYOF | c.4212T>G p.P1404= | Silent (SNP) | VAF 34/246 reads (14%) | called by muse, mutect2, varscan2
- MYOM2 | c.2964C>T p.D988= | Silent (SNP) | VAF 34/334 reads (10%) | catalogued as rs139273975, COSV50701992; called by muse, mutect2
- NEB | c.9402C>T p.D3134= | Silent (SNP) | VAF 29/262 reads (11%) | called by muse, mutect2, varscan2
- NEB | c.5535C>T p.H1845= | Silent (SNP) | VAF 42/309 reads (14%) | called by muse, mutect2, varscan2
- NLRP12 | c.720C>T p.F240= | Silent (SNP) | VAF 69/384 reads (18%) | called by muse, mutect2, varscan2
- NOL4 | c.192G>A p.L64= | Silent (SNP) | VAF 47/352 reads (13%) | called by muse, mutect2, varscan2
- NOVA1 | c.1137G>A p.T379= | Silent (SNP) | VAF 60/350 reads (17%) | catalogued as rs144344947, COSV57478512; called by muse, mutect2, varscan2
- NT5C2 | c.852C>T p.D284= | Silent (SNP) | VAF 47/271 reads (17%) | catalogued as rs367849606; called by muse, mutect2, varscan2
- NXNL2 | c.264C>T p.G88= | Silent (SNP) | VAF 43/331 reads (13%) | catalogued as rs1280002095; called by muse, mutect2, varscan2
- NXPH1 | c.255A>G p.Q85= | Silent (SNP) | VAF 46/355 reads (13%) | called by muse, mutect2, varscan2
- OAS2 | c.1539G>A p.S513= | Silent (SNP) | VAF 34/257 reads (13%) | catalogued as rs374996888; called by muse, mutect2, varscan2
- OLIG1 | c.204T>C p.A68= | Silent (SNP) | VAF 57/504 reads (11%) | called by muse, varscan2
- OR2G2 | c.519G>A p.G173= | Silent (SNP) | VAF 124/405 reads (31%) | called by muse, mutect2, varscan2
- OR8G1 | c.318T>G p.V106= | Silent (SNP) | VAF 60/341 reads (18%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1812C>T p.N604= | Silent (SNP) | VAF 36/298 reads (12%) | catalogued as rs782172657; called by muse, mutect2, varscan2
- PCDHGA2 | c.2043C>T p.S681= | Silent (SNP) | VAF 69/591 reads (12%) | catalogued as rs760848741, COSV53916701, COSV53930705; called by muse, mutect2, varscan2
- PCDHGA8 | c.1983C>T p.T661= | Silent (SNP) | VAF 50/452 reads (11%) | catalogued as COSV53986423; called by muse, mutect2, varscan2
- PCDHGA9 | c.237G>A p.P79= | Silent (SNP) | VAF 38/358 reads (11%) | catalogued as rs1234686339, COSV99529111; called by muse, mutect2, varscan2
- PCLO | c.4707T>G p.A1569= | Silent (SNP) | VAF 53/309 reads (17%) | catalogued as COSV61623943, COSV61631831; called by muse, mutect2, varscan2
- PLA2R1 | c.2928A>G p.K976= | Silent (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- PLXNA4 | c.594C>A p.T198= | Silent (SNP) | VAF 55/363 reads (15%) | called by muse, mutect2, varscan2
- POLM | c.165C>T p.G55= | Silent (SNP) | VAF 63/415 reads (15%) | called by muse, mutect2, varscan2
- PRDM13 | c.1254G>A p.A418= | Silent (SNP) | VAF 71/482 reads (15%) | called by muse, varscan2
- PSG5 | c.900T>G p.T300= | Silent (SNP) | VAF 47/341 reads (14%) | catalogued as COSV61655596; called by muse, mutect2, varscan2
- RBMXL3 | c.546A>G p.A182= | Silent (SNP) | VAF 84/268 reads (31%) | called by muse, mutect2, varscan2
- RESF1 | c.3663T>C p.T1221= | Silent (SNP) | VAF 45/269 reads (17%) | called by muse, mutect2, varscan2
- ROPN1L | c.447C>T p.C149= | Silent (SNP) | VAF 43/242 reads (18%) | catalogued as rs753462592, COSV56873528; called by muse, mutect2, varscan2
- SCN2A | c.1443A>G p.G481= | Silent (SNP) | VAF 31/334 reads (9%) | called by muse, mutect2
- SHANK1 | c.2586C>T p.F862= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as rs1216154072, COSV53243998; called by muse, mutect2, varscan2
- SLC28A1 | c.585C>T p.C195= | Silent (SNP) | VAF 107/275 reads (39%) | called by muse, mutect2, varscan2
- SLF1 | c.2865C>T p.G955= | Silent (SNP) | VAF 25/243 reads (10%) | called by muse, mutect2, varscan2
- SOX11 | c.441C>T p.G147= | Silent (SNP) | VAF 64/516 reads (12%) | called by muse, mutect2, varscan2
- SPEG | c.936G>A p.P312= | Silent (SNP) | VAF 63/663 reads (10%) | catalogued as rs1370503919, COSV100404957; called by muse, mutect2
- TBC1D32 | c.1248T>C p.T416= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- TDRD12 | c.2871C>T p.D957= (on ENST00000444215; = p.D962= on NM_001366102.1) | Silent (SNP) | VAF 32/225 reads (14%) | catalogued as rs1349496978; called by muse, mutect2, varscan2
- TEX13C | c.2376A>G p.R792= | Silent (SNP) | VAF 77/278 reads (28%) | called by muse, mutect2, varscan2
- TFDP1 | c.708G>A p.L236= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- THSD1 | c.2445G>A p.T815= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as rs757074377; called by muse, mutect2, varscan2
- THSD7A | c.2163T>C p.T721= | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- TLL1 | c.1677C>T p.D559= | Silent (SNP) | VAF 33/281 reads (12%) | catalogued as rs142933283; called by muse, mutect2, varscan2
- TMEM178B | c.201G>A p.A67= | Silent (SNP) | VAF 44/458 reads (10%) | called by muse, mutect2
- TRIM58 | c.1059A>G p.G353= | Silent (SNP) | VAF 46/478 reads (10%) | called by muse, mutect2
- TRIM71 | c.309G>A p.A103= | Silent (SNP) | VAF 61/451 reads (14%) | catalogued as COSV67472907; called by muse, mutect2, varscan2
- TTN | c.44133C>G p.P14711= (on ENST00000591111; = p.P7287= on NM_003319.4) | Silent (SNP) | VAF 31/264 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.24724A>C p.R8242= (on ENST00000591111; = p.R7315= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/252 reads (17%) | called by muse, mutect2, varscan2
- TUBB4A | c.450G>A p.L150= | Silent (SNP) | VAF 29/290 reads (10%) | called by muse, mutect2, varscan2
- UNC5D | c.2214A>G p.P738= | Silent (SNP) | VAF 40/375 reads (11%) | called by muse, mutect2, varscan2
- WDR25 | c.1470G>A p.T490= | Silent (SNP) | VAF 55/342 reads (16%) | catalogued as rs759804707; called by muse, mutect2, varscan2
- WDR97 | c.3150C>T p.S1050= | Silent (SNP) | VAF 50/564 reads (9%) | catalogued as rs1168561492; called by muse, mutect2
- ZNF335 | c.2322C>T p.G774= | Silent (SNP) | VAF 36/317 reads (11%) | catalogued as rs149480604; called by muse, mutect2, varscan2
- ZNF518B | c.45C>T p.G15= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as rs758663868; called by muse, mutect2
- ZNF69 | c.1054A>C p.R352= | Silent (SNP) | VAF 46/332 reads (14%) | called by muse, mutect2, varscan2
- ZNF723 | c.1383T>C p.A461= | Silent (SNP) | VAF 27/210 reads (13%) | catalogued as rs879219222; called by muse, mutect2, varscan2
- ZNF730 | c.1014A>G p.K338= | Silent (SNP) | VAF 31/339 reads (9%) | catalogued as rs751848978, COSV74168229; called by muse, mutect2
- ZNF750 | c.1620C>T p.T540= | Silent (SNP) | VAF 65/467 reads (14%) | catalogued as rs776087579, COSV53962136; called by muse, mutect2, varscan2
- ZNF80 | c.789G>A p.Q263= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as COSV57360164, COSV57362857; called by muse, mutect2, varscan2
- ZNF804B | c.1701T>G p.T567= | Silent (SNP) | VAF 30/251 reads (12%) | called by muse, mutect2, varscan2
- ZNF98 | c.367A>C p.R123= | Silent (SNP) | VAF 20/367 reads (5%) | catalogued as rs1279904981, COSV63335342, COSV63340837; called by muse, mutect2
- ZP2 | c.1596C>T p.N532= | Silent (SNP) | VAF 51/281 reads (18%) | called by muse, mutect2, varscan2
- C8orf86 | n.611T>A | RNA (SNP) | VAF 55/460 reads (12%) | called by muse, mutect2, varscan2
- CYFIP1 | chr15:22867209 A>G | 3'Flank (SNP) | VAF 41/261 reads (16%) | catalogued as rs970507721; called by muse, mutect2, varscan2
- DCHS2 | n.7650C>T | RNA (SNP) | VAF 47/293 reads (16%) | catalogued as rs140647788; called by muse, mutect2, varscan2
- FAAP20 | chr1:2185500 G>A | 3'Flank (SNP) | VAF 38/282 reads (13%) | catalogued as rs899031972; called by muse, mutect2, varscan2
- FAM122A | c.-12C>T | 5'UTR (SNP) | VAF 59/470 reads (13%) | catalogued as rs1042524620; called by muse, mutect2, varscan2
- FMNL1 | c.*48G>A | 3'UTR (SNP) | VAF 131/428 reads (31%) | catalogued as rs764503002; called by muse, mutect2, varscan2
- IGHG4 | chr14:105621934 T>G | 3'Flank (SNP) | VAF 28/360 reads (8%) | called by muse, mutect2
- KYAT3 | c.*55T>G | 3'UTR (SNP) | VAF 30/310 reads (10%) | catalogued as COSV53100659; called by muse, mutect2, varscan2
- MYO18B | chr22:26030961 A>C | 3'Flank (SNP) | VAF 28/311 reads (9%) | called by muse, mutect2
- PDZRN3 | c.919-29280A>C | Intron (SNP) | VAF 35/249 reads (14%) | called by muse, varscan2
- PKD1L2 | n.2676C>T | RNA (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- PTPA | c.999+39G>A | Intron (SNP) | VAF 44/318 reads (14%) | catalogued as rs576694809, COSV100533959; called by muse, varscan2
- TCP10L3 | n.441G>A | RNA (SNP) | VAF 28/300 reads (9%) | catalogued as rs752965559; called by muse, mutect2, varscan2
